Somatic mutation profile of tumor specimen MP2PRT-PAUPUE-TMP1-A (aliquot MP2PRT-PAUPUE-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUPUE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.2 years (1,910 days).
Specimen MP2PRT-PAUPUE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae63b9cc-af2d-4c70-8d35-e265f6c72a6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPUE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPUE-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c04af7a5-fa47-479a-928f-280d807d2132

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK1D | c.1019G>A p.S340N | Missense Mutation (SNP) | VAF 166/688 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV66618058; called by muse, mutect2, varscan2
- CBL | c.1165A>G p.K389E | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1060500676; ClinVar: uncertain significance; called by muse, mutect2
- FAT1 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 133/533 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs758383716, COSV71673004; called by muse, mutect2, varscan2
- LRBA | c.3825+1G>A p.X1275_splice | Splice Site (SNP) | VAF 47/202 reads (23%) | catalogued as rs769642175; called by muse, mutect2
- MUC5B | c.16066G>A p.D5356N | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs1564952568; called by muse, varscan2
- OR51D1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 135/346 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374266379; called by muse, mutect2, varscan2
- PFKFB3 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 101/397 reads (25%) | PolyPhen benign (0.065); catalogued as rs921149266; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1324C>T p.R442W (on ENST00000352766; = p.R363W on NM_181334.5) | Missense Mutation (SNP) | VAF 187/516 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs536047415; called by muse, mutect2, varscan2
- RIMBP2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs201181586, COSV55480180; called by muse, mutect2, varscan2
- ZNF77 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as rs745703143, COSV58822204; called by muse, mutect2, varscan2
- FAM24A | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 141/511 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD17B10 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 161/488 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL13 | c.1238G>T p.R413I | Missense Mutation (SNP) | VAF 152/504 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYOM3 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 130/392 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.807); called by muse, mutect2
- SLC25A31 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 122/555 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PODXL2 | c.1335C>T p.H445= | Silent (SNP) | VAF 152/388 reads (39%) | called by muse, mutect2, varscan2
- SCN2A | c.5427G>A p.A1809= | Silent (SNP) | VAF 149/393 reads (38%) | catalogued as rs1177406324, COSV51837565, COSV51853203; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GPR161 | c.-18C>T | 5'UTR (SNP) | VAF 69/200 reads (35%) | catalogued as rs1383560797; called by muse, mutect2, varscan2
